Somatic mutation profile of tumor specimen 0DB97Z from CCDI case PBBKXH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tumor cells, malignant; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 0.5 years (172 days).
Specimen 0DB97Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a9c398c-532e-42c2-b48e-3729a4be8762.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB97N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/147b38d3-7819-4ccd-a446-a08a58e3d43f

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRAK1BP1 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 444/974 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 22/225 reads (10%) | catalogued as COSV99987084; called by muse, varscan2
